Gene-level copy-number profile of tumor specimen HCM-WCMC-0751-C54-01A from HCMI case HCM-WCMC-0751-C54, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, secretory variant; Tissue or organ of origin: Endometrium; AJCC pathologic stage: Stage IA; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 54.6 years (19,958 days).
Specimen HCM-WCMC-0751-C54-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 534c95bb-9124-4369-aad6-00b3991874f7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-0751-C54-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/8ed984bc-e5eb-4649-9dab-1f43320b0b43

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 115; copy number 2: 57,748; copy number 3: 533.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 115. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
